Somatic mutation profile of tumor specimen TCGA-HE-A5NH-01A (aliquot TCGA-HE-A5NH-01A-11D-A26P-10) from TCGA case TCGA-HE-A5NH, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-HE-A5NH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85f685a8-290e-4167-98fd-e2fbe7d183d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-A5NH-10A (Blood Derived Normal), aliquot TCGA-HE-A5NH-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f0e5c67-a602-494f-853d-f3c0ca17e6df

The open-access MAF lists 90 somatic variants for this specimen: 71 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 9, Frame Shift Del 4, 3'UTR 4, Frame Shift Ins 3, Splice Site 3, RNA 2, Intron 2, In Frame Del 1, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM12 | c.464A>C p.E155A | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64115538; called by muse, mutect2, varscan2
- ALPK3 | c.4941G>C p.R1647S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51940865; called by muse, mutect2, varscan2
- ARAP2 | c.5065C>T p.R1689W | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs377015356, COSV58288040; called by muse, mutect2, varscan2
- ARCN1 | c.1203T>G p.N401K | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs546784519, COSV50617941; called by muse, mutect2, varscan2
- ATP11C | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59575547; called by muse, mutect2, varscan2
- BHLHE41 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54379817; called by muse, mutect2, varscan2
- CALCB | c.143T>A p.L48H | Missense Mutation (SNP) | VAF 163/384 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV100158138, COSV60834929; called by muse, mutect2, varscan2
- CCDC9 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55723050; called by muse, mutect2, varscan2
- CCDC9B | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs762002395, COSV66875362, COSV66876375; called by muse, mutect2, varscan2
- CCNI2 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as rs1267572677, COSV51525253; called by muse, mutect2, varscan2
- CFAP65 | c.3859G>A p.G1287S | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58566896; called by muse, mutect2, varscan2
- CRNKL1 | c.1213T>A p.F405I | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV66107294; called by muse, mutect2, varscan2
- CUBN | c.8448C>G p.I2816M | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs774977786, COSV64712966; called by muse, mutect2, varscan2
- CYP4F8 | c.1394C>G p.P465R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV57855633; called by muse, mutect2, varscan2
- DGCR8 | c.1306+1G>C p.X436_splice | Splice Site (SNP) | VAF 23/51 reads (45%) | catalogued as COSV61228926; called by muse, mutect2, varscan2
- DZIP1L | c.652T>A p.W218R | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.84); PolyPhen benign (0.014); catalogued as COSV59523803; called by muse, mutect2, varscan2
- EVI5 | c.1868A>T p.K623I | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV64830519; called by muse, mutect2, varscan2
- FAM13B | c.60A>G p.I20M | Missense Mutation (SNP) | VAF 110/235 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV50376039; called by muse, mutect2, varscan2
- FAM217A | c.1415T>C p.L472P | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs1357912316, COSV51162930; called by muse, mutect2, varscan2
- FAM53B | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as rs1247495908, COSV61561869; called by muse, mutect2, varscan2
- FUT6 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54608938, COSV99744202; called by muse, mutect2, varscan2
- GCLC | c.1348C>G p.L450V (on ENST00000643939; = p.L448V on NM_001498.4) | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.775); catalogued as COSV57598052; called by muse, mutect2, varscan2
- GPSM2 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51444856; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 69/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100736464; called by muse, mutect2, varscan2
- HMCN1 | c.11099A>G p.K3700R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV54945835; called by muse, mutect2, varscan2
- IFNL3 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201018323, COSV101308023, COSV69830241; called by muse, mutect2, varscan2
- IGSF9B | c.3776C>T p.S1259F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV58073546; called by muse, mutect2, varscan2
- IL17RC | c.1372T>C p.S458P (on ENST00000295981 / NM_153461.4; = p.S372P on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs746286726, COSV55975272; called by muse, mutect2, varscan2
- ING4 | c.711-1G>A p.X237_splice (on ENST00000396807 / NM_001127582.2; = p.X236_splice on NM_016162.4) | Splice Site (SNP) | VAF 86/227 reads (38%) | catalogued as COSV99976283; called by muse, mutect2, varscan2
- JMJD1C | c.1322A>C p.K441T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV67868126; called by muse, mutect2, varscan2
- KDM5C | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 78/100 reads (78%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs782243186, COSV64769591; called by muse, mutect2, varscan2
- KIAA1755 | c.3077G>A p.R1026Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1042786291, COSV54081343; called by muse, mutect2, varscan2
- LDB1 | c.158T>C p.L53P (on ENST00000425280 / NM_001321612.2; = p.L17P on NM_003893.5) | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV63290049; called by muse, mutect2, varscan2
- LRRC8C | c.1817A>C p.H606P | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65001889; called by muse, mutect2, varscan2
- MOGAT2 | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); catalogued as rs781112029, COSV52218790, COSV52221577; called by muse, mutect2, varscan2
- MYLIP | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs773289631, COSV62767729; called by muse, mutect2, varscan2
- NBAS | c.3546C>A p.F1182L | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55739454; called by muse, mutect2, varscan2
- NPAP1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs764805101, COSV100275235, COSV61504673; called by muse, mutect2, varscan2
- NUP214 | c.1453G>C p.G485R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV63913484; called by muse, mutect2, varscan2
- OTOGL | c.4843A>T p.N1615Y (on ENST00000547103; = p.N1606Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV54024711; called by muse, mutect2, varscan2
- PIK3C2A | c.2346A>C p.R782S | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56407553; called by muse, mutect2, varscan2
- PLA2R1 | c.2668G>C p.D890H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51787635; called by muse, mutect2, varscan2
- PPFIA1 | c.2507A>T p.D836V | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs778796834, COSV54141307; called by muse, mutect2, varscan2
- PPP1CC | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV58585357; called by muse, mutect2, varscan2
- PPP2R2A | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs373174942; called by muse, mutect2, varscan2
- PRR16 | c.196C>A p.Q66K (on ENST00000407149 / NM_001300783.2; = p.Q43K on NM_016644.2) | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV65406837; called by muse, mutect2, varscan2
- PTPRM | c.3573G>T p.R1191= | Splice Region (SNP) | VAF 52/139 reads (37%) | catalogued as COSV59883842; called by muse, mutect2, varscan2
- RIF1 | c.4128A>T p.K1376N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54625236; called by muse, mutect2, varscan2
- SCAP | c.1960G>T p.V654F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs199794833, COSV55566499; called by muse, mutect2, varscan2
- SLC17A1 | c.898-1G>A p.X300_splice | Splice Site (SNP) | VAF 24/68 reads (35%) | catalogued as COSV55079184; called by muse, mutect2, varscan2
- SMIM8 | c.62A>C p.Q21P | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57641399; called by muse, mutect2, varscan2
- SNX1 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV56040256; called by muse, mutect2, varscan2
- SORL1 | c.4769T>G p.V1590G | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV52763658; called by muse, mutect2, varscan2
- SSH2 | c.2690A>T p.K897M | Missense Mutation (SNP) | VAF 97/173 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52182359; called by muse, mutect2, varscan2
- SSTR1 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV57457850; called by muse, mutect2, varscan2
- TRAPPC9 | c.1787G>C p.G596A | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66910512; called by muse, mutect2, varscan2
- TRPM5 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs1032447607, COSV50207324; called by muse, mutect2, varscan2
- TTLL4 | c.2011A>C p.K671Q | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51439858; called by muse, mutect2, varscan2
- ZBTB1 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62440006; called by muse, mutect2, varscan2
- ZNF600 | c.1589A>T p.E530V | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV57745639; called by muse, mutect2, varscan2
- ZNF668 | c.1834G>C p.G612R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as COSV56219714; called by muse, varscan2
- ZNF761 | c.1765T>G p.F589V | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV61889598; called by muse, mutect2, varscan2
- ARL13B | c.933del p.N311Kfs*6 (on ENST00000394222 / NM_001174150.2; = p.N204Kfs*6 on NM_144996.4) | Frame Shift Del (DEL) | VAF 41/156 reads (26%) | called by mutect2, pindel, varscan2
- EDEM3 | c.63del p.V22Wfs*23 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- EOMES | c.1185dup p.Y396Ifs*9 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel
- IGHM | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MTRR | c.1698del p.I567Sfs*2 (on ENST00000264668; = p.I540Sfs*2 on NM_002454.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 31/77 reads (40%) | called by mutect2, pindel, varscan2
- OR5AR1 | c.859_867del p.P287_I289del | In Frame Del (DEL) | VAF 42/173 reads (24%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.3971_3972insTT p.L1325Cfs*29 | Frame Shift Ins (INS) | VAF 76/145 reads (52%) | called by mutect2, varscan2
- SLX4 | c.1962del p.F655Lfs*36 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- WDR20 | c.457dup p.T153Nfs*26 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- ASPH | c.1644G>A p.E548= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as rs1244598508, COSV65242699, COSV65243975; called by muse, mutect2, varscan2
- CELSR1 | c.1338C>T p.Y446= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1465893049, COSV53101093; called by muse, mutect2, varscan2
- ERGIC2 | c.579T>A p.I193= | Silent (SNP) | VAF 70/191 reads (37%) | catalogued as COSV64113559; called by muse, mutect2, varscan2
- GABRB1 | c.1113C>G p.T371= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as rs1387779329, COSV55001513; called by muse, mutect2, varscan2
- LPL | c.621C>T p.D207= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as rs118204076, CM930483, COSV60933176; called by muse, mutect2, varscan2
- ODF2 | c.1833T>C p.A611= (on ENST00000434106 / NM_153433.2; = p.A587= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 85/213 reads (40%) | catalogued as rs745884611, COSV63546259, COSV63546343; called by muse, mutect2, varscan2
- SPEG | c.6966C>T p.S2322= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV56680822; called by muse, mutect2, varscan2
- UNC13C | c.3747T>A p.V1249= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as COSV52929455; called by muse, mutect2, varscan2
- ZNF436 | c.72C>T p.T24= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV58359599; called by muse, mutect2, varscan2
- ABHD13 | c.*15A>T | 3'UTR (SNP) | VAF 16/44 reads (36%) | catalogued as COSV101024253; called by muse, mutect2, varscan2
- ADO | c.*88A>G | 3'UTR (SNP) | VAF 17/55 reads (31%) | catalogued as COSV101060495; called by muse, mutect2
- ARL5C | c.46+16G>T | Intron (SNP) | VAF 60/100 reads (60%) | called by muse, mutect2, varscan2
- CCNB2 | c.-20T>A | 5'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99879166; called by muse, mutect2, varscan2
- CD300LD | chr17:74594015 G>A | 5'Flank (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- CXCR2 | c.*648T>A | 3'UTR (SNP) | VAF 91/238 reads (38%) | catalogued as COSV100579123; called by muse, mutect2, varscan2
- LINC01804 | n.469A>G | RNA (SNP) | VAF 54/110 reads (49%) | called by muse, mutect2, varscan2
- MAB21L2 | c.*115A>G | 3'UTR (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100461889, COSV100462432; called by muse, mutect2, varscan2
- MTUS1 | c.2449+1824A>T | Intron (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- PKD1L2 | n.3151G>C | RNA (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
